Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA7O, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA7O-01A (Primary Tumor).

Collect date: (MM/DD/YYYY)

CLUE ICD-O-3
Carcinoma, urothelial
papillary 8/30/13
path Carcinoma, transitional cell NOS
Site Bladder, lateral wall 8/20/13
with Bladder NOS C67.2
QW 8/18/14 C67.9

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

"Prostate + bladder":

Bladder:

- . Invasive urothelial carcinoma of high-grade
- . Depth of infiltration: up to muscularis propria
- . Size of neoplasm: 5.5 x 4.0 x 2.5 cm
- . Sanguineous vascular invasion: not detected
- . Lymphatic vascular invasion: present
- . Perineural invasion: not detected
- . Adjacent bladder mucosa: severe chronic cystitis
- . Surgical margins (urethral and ureteral): free of neoplastic involvement

Prostate:

- . Acute and chronic focal prostatitis
- . Absence of neoplasia

Right and left seminal vesicles:

- . Free of neoplasia

Right and left vas deferens:

- . Free of neoplasia

"Left iliac obturator lymph nodes":

- . 12 lymph nodes were dissected, all free of tumor (0/12)

"Right iliac obturator lymph nodes":

- . 9 lymph nodes were dissected, all free of tumor (0/9)

PATHOLOGIC STAGING

Topography	Morphology	Stage
Bladder, NOS	Transitional cell carcinoma, NOS	pT2 pN0

Source: NCI Genomic Data Commons file 01279d99-2f95-4e32-846a-c4df4a64dc88 (TCGA-4Z-AA7O.1B91CBCE-11F7-4B83-BF5B-CBA6F9CEB799.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).